Gene-level copy-number profile of tumor specimen TCGA-ZM-AA0H-01A from TCGA case TCGA-ZM-AA0H, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 50.4 years (18,419 days).
Specimen TCGA-ZM-AA0H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.175b0144-1b5d-4a71-9b31-8b6a0115df77.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZM-AA0H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/307d05b2-2cda-4cec-936f-87fe263f56ef

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 463; copy number 2: 7,024; copy number 3: 22,583; copy number 4: 12,163; copy number 5: 8,808; copy number 6: 7,805; copy number 7: 974.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZM-AA0H-01A-11D-A434-01): tumor purity 0.26, ploidy 3.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 974 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–46,876,784, 974 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 456. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
